Somatic mutation profile of tumor specimen TCGA-AX-A3G8-01A (aliquot TCGA-AX-A3G8-01A-11D-A228-09) from TCGA case TCGA-AX-A3G8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 76.4 years (27,899 days).
Specimen TCGA-AX-A3G8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed8257ef-5edb-4eaa-8ee9-b5e6f0dc1892.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A3G8-10A (Blood Derived Normal), aliquot TCGA-AX-A3G8-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f189af54-8627-4cce-a071-22d9539afa9f

The open-access MAF lists 948 somatic variants for this specimen: 732 protein-altering or splice-affecting, 201 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 458, Silent 201, Frame Shift Del 169, Frame Shift Ins 39, Nonsense Mutation 37, In Frame Del 13, Splice Site 10, Splice Region 6, RNA 3, 5'UTR 3, 3'UTR 3, 3'Flank 3.

Variants (750 of 948; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2A1 | c.2464del p.R822Gfs*49 | Frame Shift Del (DEL) | VAF 44/119 reads (37%) | catalogued as rs751365374, COSV62870629; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- DYNC2H1 | c.10024C>T p.R3342* | Nonsense Mutation (SNP) | VAF 22/34 reads (65%) | catalogued as rs751891969, COSV100520171, COSV62097172, COSV62109049; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ESCO2 | c.760del p.T254Lfs*13 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs80359852; ClinVar: pathogenic; called by mutect2, varscan2
- F8 | c.6545G>A p.R2182H | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852466, CM015870, CM111360, CM940403, COSV57704301; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 36/40 reads (90%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MLH1 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 41/94 reads (44%) | catalogued as rs63751012, CM055990, CM101371, CM1413027, COSV51615011, COSV51624704, COSV99212331; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 47/88 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs121909241, CM045431, CM063078, CM074468, COSV64288421, COSV64288528, COSV64293854; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 29/69 reads (42%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SHANK3 | c.3658del p.A1220Pfs*57 | Frame Shift Del (DEL) | VAF 20/38 reads (53%) | catalogued as rs762292772; ClinVar: pathogenic; called by mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 19/49 reads (39%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- TET2 | c.1648C>T p.R550* | Nonsense Mutation (SNP) | VAF 22/47 reads (47%) | hotspot (GDC flag); catalogued as rs572712965, COSV54395664; called by muse, mutect2, varscan2
- ABCA3 | c.2647G>A p.G883S | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs768694493, COSV100068035, COSV57057721; called by muse, mutect2, varscan2
- ABCA9 | c.496dup p.M166Nfs*4 | Frame Shift Ins (INS) | VAF 14/44 reads (32%) | catalogued as rs753442189; called by mutect2, pindel, varscan2
- AC013477.1 | c.2392G>A p.A798T | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.267); catalogued as COSV99548712; called by muse, mutect2, varscan2
- AC097636.1 | c.97del p.R33Gfs*2 | Frame Shift Del (DEL) | VAF 31/64 reads (48%) | catalogued as rs1486698948; called by mutect2, pindel, varscan2
- ACADL | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs758491059, COSV52052319; called by muse, mutect2, varscan2
- ACKR4 | c.551G>A p.C184Y | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99391591; called by muse, mutect2, varscan2
- ACP5 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99520192; called by muse, mutect2, varscan2
- ACVR2A | c.27del p.F9Lfs*65 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as COSV54021820; called by pindel, varscan2*
- ADAM22 | c.2485C>T p.R829* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV55991802; called by muse, mutect2, varscan2
- ADAMTS16 | c.2458C>T p.R820W | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747638541, COSV56995053; called by muse, mutect2, varscan2
- ADGRB2 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.673); catalogued as rs763588095, COSV99925738; called by muse, mutect2, varscan2
- ADGRD1 | c.1802G>A p.R601H | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs201524753, COSV55439764; called by muse, mutect2, varscan2
- ADGRG4 | c.3023C>A p.P1008H | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99794409; called by muse, mutect2, varscan2
- ADIG | c.160T>C p.W54R | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100972523; called by muse, mutect2, varscan2
- AFF3 | c.1354dup p.H452Pfs*8 | Frame Shift Ins (INS) | VAF 18/56 reads (32%) | catalogued as rs759949420; called by mutect2, varscan2
- AFP | c.1295T>C p.L432P | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99889710; called by muse, mutect2, varscan2
- AHCY | c.26T>C p.V9A | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.198); catalogued as COSV99464011; called by muse, mutect2, varscan2
- AK9 | c.1073G>T p.S358I | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99572345; called by muse, mutect2, varscan2
- AMER3 | c.1816C>T p.R606* | Nonsense Mutation (SNP) | VAF 34/74 reads (46%) | catalogued as rs781541050, COSV100365992; called by muse, mutect2, varscan2
- ANK1 | c.3305A>C p.K1102T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99224011; called by muse, mutect2, varscan2
- ANK1 | c.620T>C p.F207S | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV99224013; called by muse, mutect2
- ANK2 | c.11681C>T p.T3894I | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.133); catalogued as rs1318639708, COSV52153228; called by muse, mutect2, varscan2
- ANO7 | c.37G>T p.G13W | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99237436; called by muse, mutect2, varscan2
- ANP32A | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV51189663; called by muse, mutect2, varscan2
- APOB | c.12660C>A p.F4220L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99263701; called by muse, mutect2, varscan2
- AREG | c.334dup p.Q112Pfs*7 | Frame Shift Ins (INS) | VAF 88/232 reads (38%) | catalogued as rs757742243; called by mutect2, varscan2
- ARHGAP22 | c.1334del p.G445Afs*18 | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | catalogued as rs748723326; called by mutect2, pindel, varscan2
- ARHGAP32 | c.5299G>T p.G1767W (on ENST00000310343 / NM_001378025.1; = p.G1418W on NM_014715.4) | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100086932; called by muse, mutect2, varscan2
- ARHGAP35 | c.4171A>G p.M1391V | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101350716; called by muse, mutect2, varscan2
- ARHGEF11 | c.3467C>T p.A1156V | Missense Mutation (SNP) | VAF 64/92 reads (70%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100168289; called by muse, mutect2, varscan2
- ARHGEF5 | c.4540dup p.Q1514Pfs*14 | Frame Shift Ins (INS) | VAF 39/96 reads (41%) | catalogued as rs1240015587; called by mutect2, pindel, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARL6IP1 | c.493+2T>C p.X165_splice | Splice Site (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100435779; called by muse, mutect2, varscan2
- ARMCX6 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1387134973, COSV100726218; called by muse, mutect2
- ASH1L | c.5875G>A p.A1959T | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); catalogued as COSV100853121; called by muse, mutect2, varscan2
- ASMTL | c.904C>T p.L302F | Missense Mutation (SNP) | VAF 89/223 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101187655; called by muse, mutect2, varscan2
- ASXL3 | c.3163G>A p.A1055T | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1165991321, COSV52462427; called by muse, mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | catalogued as rs746676748; called by mutect2, varscan2
- ATG2B | c.2783A>G p.K928R | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0.368); catalogued as COSV100737713; called by muse, mutect2, varscan2
- ATP4A | c.1828G>A p.V610I | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773568287, COSV52865825, COSV52872123; called by muse, varscan2
- ATP4A | c.1755G>T p.E585D | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99382146; called by muse, varscan2
- ATP6V1B1 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as rs1553415274, COSV52266531; called by muse, mutect2, varscan2
- ATXN7L1 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs752567780, COSV100596741; called by muse, mutect2, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 26/54 reads (48%) | catalogued as rs35951843; called by mutect2, varscan2
- BACE2 | c.1501del p.R501Vfs*20 | Frame Shift Del (DEL) | VAF 21/57 reads (37%) | catalogued as COSV100160427; called by mutect2, pindel, varscan2
- BCAR3 | c.1550C>A p.P517H | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99550267; called by muse, mutect2, varscan2
- BCAR3 | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 30/68 reads (44%) | catalogued as rs1188738667, COSV53078333, COSV53079237; called by muse, mutect2, varscan2
- BCL9 | c.3743C>T p.T1248M | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs138508726; called by muse, mutect2, varscan2
- BDP1 | c.824T>C p.V275A | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100702736; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs755506199; called by mutect2, varscan2
- BMS1 | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 75/201 reads (37%) | catalogued as COSV100996470; called by muse, mutect2, varscan2
- BPIFB3 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775535713, COSV64958451; called by muse, mutect2, varscan2
- BRSK1 | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 38/78 reads (49%) | catalogued as rs746043904, COSV58665984; called by mutect2, varscan2
- BRWD3 | c.3203A>T p.E1068V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.119); catalogued as COSV100955661; called by muse, mutect2, varscan2
- BTAF1 | c.2950A>G p.T984A | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.07); catalogued as COSV99794912; called by muse, mutect2, varscan2
- C1GALT1C1 | c.949A>G p.N317D | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100485567; called by muse, mutect2, varscan2
- CA13 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs771065915, COSV100410027; called by muse, mutect2, varscan2
- CABLES1 | c.1307G>A p.G436D (on ENST00000256925 / NM_001100619.2; = p.G171D on NM_138375.2) | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV99908320; called by muse, mutect2, varscan2
- CACNA1I | c.4618G>A p.A1540T | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100359276; called by muse, mutect2, varscan2
- CACTIN | c.2176C>T p.R726C | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50269571; called by muse, mutect2, varscan2
- CADM4 | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.771); catalogued as COSV99731365; called by muse, mutect2, varscan2
- CAMSAP3 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.582); catalogued as COSV50342012; called by muse, mutect2, varscan2
- CAMTA1 | c.4620C>T p.G1540= | Splice Region (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100346408; called by muse, mutect2, varscan2
- CARMIL1 | c.2389G>A p.A797T | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100276922; called by muse, mutect2, varscan2
- CARMIL2 | c.4252G>A p.E1418K | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.534); catalogued as COSV99537425; called by muse, mutect2, varscan2
- CCDC134 | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs369237416; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 58/131 reads (44%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC57 | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100492394; called by muse, mutect2
- CCDC65 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs763737404, COSV57197404; called by muse, mutect2, varscan2
- CCDC80 | c.975G>T p.E325D | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99244284; called by muse, mutect2, varscan2
- CCN4 | c.568A>G p.K190E | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as COSV99136963; called by muse, mutect2, varscan2
- CD163 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1245375046, COSV100775673; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH2 | c.2438C>A p.P813H | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99295740; called by muse, mutect2, varscan2
- CDH23 | c.6899A>G p.Y2300C | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99818947; called by muse, mutect2
- CDK3 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs761700729, COSV100043980; called by muse, mutect2, varscan2
- CDS1 | c.789del p.F263Lfs*6 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs759091263; called by mutect2, varscan2
- CECR2 | c.1423A>G p.I475V (on ENST00000342247 / NM_001290047.2; = p.I292V on NM_001290046.1) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); catalogued as COSV99377046; called by muse, mutect2, varscan2
- CELSR2 | c.4865G>A p.S1622N | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99603081; called by muse, mutect2, varscan2
- CEP350 | c.2354A>G p.H785R | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as rs1047808363, COSV100854319; called by muse, mutect2, varscan2
- CEP44 | c.847G>C p.V283L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV99639197; called by muse, mutect2, varscan2
- CFAP206 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs371084143, COSV99739571; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | catalogued as COSV99267225; called by muse, mutect2, varscan2
- CFAP43 | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.686); catalogued as rs373422223; called by muse, mutect2, varscan2
- CHAF1A | c.1747G>A p.A583T | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs1440540090, COSV100010841, COSV100011137; called by muse, mutect2, varscan2
- CHAMP1 | c.962G>T p.R321M | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100778722; called by muse, mutect2, varscan2
- CHD6 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.037); catalogued as rs199798781; called by muse, mutect2, varscan2
- CHEK1 | c.676dup p.T226Nfs*19 | Frame Shift Ins (INS) | VAF 30/63 reads (48%) | catalogued as rs757716680; called by mutect2, varscan2
- CHERP | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs763728092, COSV99550001; called by muse, mutect2, varscan2
- CHRNA3 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs199640841, CM0910890; called by muse, mutect2, varscan2
- CHRNB3 | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769737518, COSV51493891; called by muse, mutect2, varscan2
- CHUK | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1174137888, COSV100956989; called by muse, mutect2, varscan2
- CIAO3 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs143253710; called by muse, mutect2, varscan2
- CLSPN | c.1947G>T p.K649N | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99230319; called by muse, mutect2, varscan2
- CMBL | c.559-1G>A p.X187_splice | Splice Site (SNP) | VAF 35/75 reads (47%) | catalogued as COSV99686889; called by muse, mutect2, varscan2
- CNOT1 | c.5363T>C p.I1788T | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV99799281; called by muse, mutect2, varscan2
- COG1 | c.2875A>G p.S959G | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100245135; called by muse, mutect2, varscan2
- COL11A2 | c.1899G>T p.Q633H (on ENST00000341947 / NM_080680.3; = p.Q526H on NM_080679.2) | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100553455; called by muse, mutect2, varscan2
- COL16A1 | c.4471G>A p.G1491R | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99593607; called by muse, mutect2, varscan2
- COL1A2 | c.4012C>T p.R1338C | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781721538, COSV51953052; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A1 | c.1209del p.G404Efs*101 | Frame Shift Del (DEL) | VAF 57/130 reads (44%) | catalogued as rs1253250417, COSV62616066; called by mutect2, pindel, varscan2
- COL6A3 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); catalogued as rs189356869, COSV55086821; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CORO1A | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs371653086; called by muse, mutect2, varscan2
- CPEB1 | c.1603C>T p.R535C (on ENST00000617958; = p.R470C on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55618771, COSV55620131; called by muse, mutect2, varscan2
- CPPED1 | c.781A>G p.M261V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV99902783; called by muse, mutect2, varscan2
- CPQ | c.142A>G p.K48E | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV99610657; called by muse, mutect2, varscan2
- CR2 | c.1045G>A p.V349I | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.081); catalogued as rs374421007; called by muse, mutect2, varscan2
- CRIP2 | c.513G>T p.Q171H | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.925); catalogued as COSV100231582; called by muse, mutect2
- CRYGA | c.476dup p.A160Cfs*29 | Frame Shift Ins (INS) | VAF 28/60 reads (47%) | catalogued as rs762650691; called by mutect2, varscan2
- CSMD2 | c.4854del p.C1619Vfs*224 | Frame Shift Del (DEL) | VAF 7/67 reads (10%) | catalogued as COSV53883753; called by mutect2, pindel, varscan2
- CTNNBIP1 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as rs548974391, COSV101032689; called by muse, mutect2, varscan2
- CUL4B | c.2453T>C p.L818P | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100340146; called by muse, mutect2, varscan2
- CYP26B1 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV99134248; called by muse, mutect2, varscan2
- CYP2B6 | c.545T>C p.I182T | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as COSV100137298; called by muse, mutect2, varscan2
- CYP39A1 | c.270del p.V91* | Frame Shift Del (DEL) | VAF 24/58 reads (41%) | catalogued as rs1225765844; called by mutect2, pindel, varscan2
- CYP4B1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV99596809; called by muse, mutect2, varscan2
- DBN1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.143); catalogued as rs1416082865, COSV99445551; called by muse, mutect2, varscan2
- DCTN2 | c.599dup p.D201Rfs*2 (on ENST00000548249 / NM_001261413.2; = p.D206Rfs*2 on NM_006400.4) | Frame Shift Ins (INS) | VAF 50/104 reads (48%) | catalogued as rs745744034; called by mutect2, varscan2
- DDX42 | c.1117C>A p.L373I | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV100834833; called by muse, mutect2, varscan2
- DDX46 | c.3055T>C p.S1019P | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV62800345; called by muse, mutect2, varscan2
- DENND3 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs902931218, COSV99370350; called by muse, varscan2
- DGKG | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as COSV99402492; called by muse, mutect2, varscan2
- DHX34 | c.3371G>A p.C1124Y | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1368859401, COSV100169247; called by muse, mutect2, varscan2
- DHX57 | c.518A>G p.E173G | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as COSV99769089; called by muse, mutect2, varscan2
- DIDO1 | c.6101del p.P2034Rfs*240 | Frame Shift Del (DEL) | VAF 20/43 reads (47%) | catalogued as COSV56634983; called by mutect2, varscan2
- DIDO1 | c.2014C>T p.Q672* | Nonsense Mutation (SNP) | VAF 41/114 reads (36%) | catalogued as COSV99824807; called by muse, mutect2, varscan2
- DLG2 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 24/51 reads (47%) | catalogued as COSV54689884; called by muse, mutect2, varscan2
- DMXL1 | c.8800G>A p.V2934I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs752290889, COSV60706638; called by muse, mutect2, varscan2
- DNAH17 | c.13079A>T p.N4360I | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV99428014; called by muse, mutect2
- DNAH5 | c.5568G>A p.M1856I | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV99445286; called by muse, mutect2, varscan2
- DNAH7 | c.1037del p.K346Sfs*23 | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | catalogued as rs761292636; called by mutect2, varscan2
- DNAI4 | c.2409_2412del p.T804Ifs*5 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as rs780832715; called by pindel, varscan2
- DNAJC15 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV101004929; called by muse, mutect2, varscan2
- DNAJC16 | c.892_895del p.L298Hfs*9 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs1311840276; called by pindel, varscan2
- DNM1 | c.590G>A p.G197D | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100359517; called by muse, mutect2, varscan2
- DNMT1 | c.341G>T p.R114I | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV100531772; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 32/90 reads (36%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DRD5 | c.568G>T p.G190W | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs144132215, COSV58576684, COSV58579946; called by muse, mutect2, varscan2
- DSCAML1 | c.845C>T p.A282V (on ENST00000321322; = p.A222V on NM_020693.4) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.452); catalogued as COSV100354644; called by muse, mutect2, varscan2
- DSP | c.724C>A p.L242M | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.902); catalogued as COSV101131183; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 9/14 reads (64%) | catalogued as rs746928635; called by mutect2, varscan2
- DYRK1B | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as COSV55683302; called by muse, mutect2, varscan2
- E2F4 | c.653G>A p.S218N | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100103585; called by muse, mutect2, varscan2
- EAF2 | c.334dup p.T112Nfs*4 | Frame Shift Ins (INS) | VAF 17/37 reads (46%) | catalogued as rs746509911; called by mutect2, varscan2
- ECM2 | c.2074G>A p.V692I | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.204); catalogued as rs183564221, COSV60743474; called by muse, mutect2, varscan2
- EDN3 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.081); catalogued as rs767453373, COSV100284783; called by muse, mutect2, varscan2
- EEF1B2 | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99260411; called by muse, mutect2, varscan2
- EGR2 | c.824del p.G275Afs*6 | Frame Shift Del (DEL) | VAF 40/97 reads (41%) | catalogued as COSV99653876; called by mutect2, pindel, varscan2
- EIF4E2 | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV99298948, COSV99299113; called by muse, mutect2
- EIF5B | c.1544C>T p.T515I | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs778447265, COSV99176816; called by muse, varscan2
- ELK4 | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 121/154 reads (79%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV56986760; called by muse, mutect2, varscan2
- ENDOU | c.235_236insA p.L79Hfs*21 (on ENST00000422538 / NM_001172439.2; = p.L38Hfs*21 on NM_006025.4) | Frame Shift Ins (INS) | VAF 16/30 reads (53%) | catalogued as COSV99968196; called by mutect2, varscan2
- ENTPD5 | c.1086G>A p.V362= | Splice Region (SNP) | VAF 26/53 reads (49%) | catalogued as COSV100592147; called by muse, mutect2, varscan2
- EPHA8 | c.2388+1G>A p.X796_splice | Splice Site (SNP) | VAF 28/56 reads (50%) | catalogued as rs1265050218, COSV99384261; called by muse, mutect2, varscan2
- EPX | c.1055A>T p.D352V | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.054); catalogued as COSV99836244; called by muse, mutect2, varscan2
- ERCC4 | c.1460del p.K487Rfs*6 | Frame Shift Del (DEL) | VAF 9/19 reads (47%) | catalogued as COSV61313893; called by mutect2, varscan2
- ERICH3 | c.2818A>C p.S940R | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100443442; called by muse, mutect2, varscan2
- ERMP1 | c.1951dup p.T651Nfs*25 | Frame Shift Ins (INS) | VAF 27/64 reads (42%) | catalogued as rs753821453; called by mutect2, varscan2
- EVPL | c.2485C>T p.R829C | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs763778048, COSV100043982, COSV100044579; called by muse, mutect2, varscan2
- EXT1 | c.963-1G>T p.X321_splice | Splice Site (SNP) | VAF 14/34 reads (41%) | catalogued as CS099208, CS130815, COSV100983580; called by muse, mutect2, varscan2
- FAM131B | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as rs757750227, COSV68125404; called by muse, mutect2, varscan2
- FAM135B | c.4105G>A p.A1369T | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52709117, COSV52732702; called by muse, mutect2, varscan2
- FAM200A | c.84G>T p.E28D | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.482); catalogued as COSV101282702; called by muse, mutect2, varscan2
- FAM20B | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 49/68 reads (72%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.995); catalogued as COSV55382809; called by muse, mutect2, varscan2
- FAM47C | c.1750C>A p.P584T | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV63730844; called by muse, mutect2, varscan2
- FASN | c.2701C>T p.R901C | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs768819928, COSV100147329; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBRS | c.597C>T p.F199= (on ENST00000287468; = p.F719= on NM_001105079.3) | Splice Region (SNP) | VAF 38/81 reads (47%) | catalogued as COSV54915647; called by muse, mutect2, varscan2
- FBRS | c.1064G>A p.R355H (on ENST00000287468; = p.R875H on NM_001105079.3) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as rs758839126, COSV99788840; called by muse, varscan2
- FBXL7 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs771652620, COSV61647711; called by muse, mutect2, varscan2
- FBXL8 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99263412; called by muse, mutect2, varscan2
- FBXO34 | c.1582G>A p.A528T | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV100571844; called by muse, mutect2, varscan2
- FCRLA | c.698A>G p.Y233C (on ENST00000367959; = p.Y210C on NM_032738.4) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99375672; called by muse, mutect2, varscan2
- FGD3 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs761872378, COSV61598410; called by muse, mutect2, varscan2
- FGFR4 | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.9); PolyPhen benign (0.011); catalogued as COSV99448851; called by muse, mutect2, varscan2
- FMO1 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs28360433; called by muse, mutect2, varscan2
- FNDC1 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs769525298, COSV51948229; called by muse, mutect2, varscan2
- FOCAD | c.701T>C p.V234A | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100620059; called by muse, mutect2, varscan2
- FRYL | c.1973del p.N658Tfs*8 | Frame Shift Del (DEL) | VAF 45/123 reads (37%) | catalogued as rs758807551; called by mutect2, pindel, varscan2
- FSTL4 | c.2369del p.G790Vfs*6 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | catalogued as rs765771244; called by mutect2, pindel, varscan2
- GADD45A | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374796115; called by muse, mutect2, varscan2
- GAS7 | c.644G>A p.G215D (on ENST00000432992 / NM_201433.2; = p.G75D on NM_003644.3) | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.202); catalogued as COSV100094605; called by muse, mutect2, varscan2
- GATA3 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1343882720, COSV60523322; called by muse, mutect2, varscan2
- GCM1 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99452117; called by muse, mutect2
- GDF2 | c.1207G>A p.V403I | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs367957332; called by muse, mutect2, varscan2
- GEMIN4 | c.3139C>T p.R1047W | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.731); catalogued as rs373429888; called by muse, mutect2, varscan2
- GIGYF1 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs781040173, COSV51939511; called by muse, mutect2, varscan2
- GLB1L | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV55477882, COSV99850250; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 20/63 reads (32%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GLI3 | c.124+2T>C p.X42_splice | Splice Site (SNP) | VAF 24/72 reads (33%) | catalogued as COSV101229731; called by muse, mutect2, varscan2
- GPAT2 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV100853218; called by muse, mutect2, varscan2
- GPATCH3 | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 41/89 reads (46%) | catalogued as COSV100658693; called by muse, mutect2, varscan2
- GPSM1 | c.1778A>G p.Q593R | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.662); catalogued as COSV99395836; called by muse, mutect2, varscan2
- GREB1 | c.997G>T p.G333W | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as COSV99302263; called by muse, mutect2, varscan2
- GRID1 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.098); catalogued as rs371302230; called by muse, mutect2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIK4 | c.1809del p.F604Sfs*27 | Frame Shift Del (DEL) | VAF 33/100 reads (33%) | catalogued as COSV70801839; called by mutect2, pindel, varscan2
- GRK3 | c.1374G>A p.W458* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as rs751028149, COSV100151111; called by muse, mutect2, varscan2
- GRM1 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1196671438, COSV51159383, COSV51197406; called by muse, mutect2, varscan2
- GRN | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs200591137, COSV99274586; called by muse, mutect2, varscan2
- GTPBP1 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs920670732, COSV99322931; called by muse, mutect2, varscan2
- GTSF1L | c.247_249del p.P83del | In Frame Del (DEL) | VAF 50/100 reads (50%) | catalogued as rs1211213000; called by pindel, varscan2
- H1-1 | c.513del p.K171Nfs*5 | Frame Shift Del (DEL) | VAF 43/114 reads (38%) | catalogued as COSV55119441; called by mutect2, pindel, varscan2
- HDAC10 | c.1843_1844insA p.P615Hfs*18 | Frame Shift Ins (INS) | VAF 36/76 reads (47%) | catalogued as COSV99352103; called by mutect2, pindel, varscan2
- HDAC3 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as rs748543297, COSV59497879; called by muse, mutect2, varscan2
- HDAC5 | c.2395A>C p.S799R | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV99870285; called by muse, varscan2
- HDHD3 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV99444787; called by muse, mutect2
- HDX | c.530C>A p.S177* | Nonsense Mutation (SNP) | VAF 39/76 reads (51%) | catalogued as COSV99946622; called by muse, mutect2, varscan2
- HEATR5B | c.6214dup p.*2072Lfs*18 | Frame Shift Ins (INS) | VAF 14/27 reads (52%) | catalogued as rs1315552549; called by mutect2, varscan2
- HEATR5B | c.4421A>G p.Q1474R | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV99248286; called by muse, mutect2, varscan2
- HECW2 | c.2531C>T p.P844L | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs762187660, COSV99645916; called by muse, mutect2, varscan2
- HERC2 | c.10315G>A p.A3439T | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs549800096, COSV99871099; called by muse, mutect2, varscan2
- HERC6 | c.2668C>T p.H890Y | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs1329024606, COSV99986346; called by muse, mutect2, varscan2
- HERPUD1 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 51/96 reads (53%) | catalogued as COSV100295843; called by muse, mutect2, varscan2
- HLA-DMB | c.492G>T p.K164N | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.082); catalogued as COSV101186814, COSV66870846; called by muse, mutect2, varscan2
- HMGCLL1 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs758293303, COSV99231457; called by muse, mutect2, varscan2
- HMGCLL1 | c.569A>G p.E190G | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV99231459; called by muse, mutect2, varscan2
- HPS1 | c.1228A>T p.K410* | Nonsense Mutation (SNP) | VAF 43/102 reads (42%) | catalogued as COSV100282338; called by muse, mutect2, varscan2
- HSD17B3 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100931237; called by muse, mutect2, varscan2
- HTR1B | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV100885334; called by muse, mutect2, varscan2
- HTR3C | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV100570500; called by muse, mutect2, varscan2
- ICE1 | c.6067C>T p.P2023S | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99663811; called by muse, mutect2, varscan2
- IGHMBP2 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs373012350; called by muse, mutect2, varscan2
- IKBKG | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.281); catalogued as COSV100852984; called by muse, mutect2, varscan2
- IL2RG | c.359del p.K120Rfs*27 | Frame Shift Del (DEL) | VAF 30/74 reads (41%) | catalogued as CD159812; called by mutect2, pindel, varscan2
- IMP4 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs113604002; called by muse, mutect2, varscan2
- INPP1 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100487112; called by muse, mutect2, varscan2
- INSR | c.2172G>T p.E724D | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100251479; called by muse, mutect2, varscan2
- INTS10 | c.1251G>T p.R417S | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.426); catalogued as COSV101208648; called by muse, mutect2, varscan2
- INTS5 | c.1198G>A p.G400R | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.743); catalogued as COSV100399473; called by muse, mutect2, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 35/81 reads (43%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- IPO9 | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV100843339; called by muse, mutect2, varscan2
- IQGAP3 | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.989); catalogued as rs1444244340, COSV100752067; called by muse, mutect2, varscan2
- IREB2 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 81/197 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99359050; called by muse, mutect2, varscan2
- IRS4 | c.3226C>T p.Q1076* | Nonsense Mutation (SNP) | VAF 22/49 reads (45%) | catalogued as COSV100929429; called by muse, mutect2, varscan2
- ITGA1 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1464210274, COSV99250707; called by muse, mutect2, varscan2
- ITGA9 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); catalogued as COSV99291685; called by muse, mutect2, varscan2
- ITGB5 | c.737C>A p.P246H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99950371; called by muse, mutect2, varscan2
- ITIH2 | c.1589C>T p.A530V | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1458232466, COSV100623163; called by muse, mutect2, varscan2
- ITPR2 | c.6535C>T p.R2179C | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101189818; called by muse, mutect2, varscan2
- ITSN1 | c.2650G>A p.A884T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV101180441; called by muse, mutect2, varscan2
- KCNC4 | c.1168C>A p.L390M | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV100873569; called by muse, mutect2, varscan2
- KCNH1 | c.2122C>T p.R708W (on ENST00000271751 / NM_172362.3; = p.R681W on NM_002238.4) | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1481569982, COSV55073719, COSV99657423; called by muse, varscan2
- KCNJ12 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs782449851, COSV100054035, COSV100054539; called by muse, mutect2, varscan2
- KCNK9 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs751012938, COSV100271423, COSV57288387; called by muse, mutect2, varscan2
- KCNQ1 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99325812; called by muse, mutect2, varscan2
- KCNS2 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs753185856, COSV99750714; called by muse, varscan2
- KDM3B | c.2743C>T p.R915C | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58689583; called by muse, mutect2, varscan2
- KDM5C | c.523C>A p.Q175K | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0.138); catalogued as COSV100855394; called by muse, mutect2, varscan2
- KEAP1 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 48/73 reads (66%) | SIFT tolerated (0.21); PolyPhen benign (0.292); catalogued as rs142453344, COSV99407349; called by muse, mutect2, varscan2
- KIAA0753 | c.1658G>A p.R553H | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs758064383, COSV100810529; called by muse, mutect2, varscan2
- KIAA0930 | c.452G>A p.S151N (on ENST00000336156 / NM_001009880.2; = p.S156N on NM_015264.2) | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs1383947646, COSV52663061; called by muse, mutect2, varscan2
- KIAA2026 | c.2379del p.K793Nfs*12 | Frame Shift Del (DEL) | VAF 19/48 reads (40%) | catalogued as rs1192880538; called by mutect2, pindel, varscan2
- KIF17 | c.707T>C p.L236P | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99928551; called by muse, mutect2
- KIF26A | c.2306C>T p.T769M | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs756922028, COSV59470971; called by muse, mutect2, varscan2
- KIF5C | c.2609G>A p.R870H | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68483397; called by muse, mutect2, varscan2
- KIRREL1 | c.1009del p.L337Sfs*14 | Frame Shift Del (DEL) | VAF 32/118 reads (27%) | catalogued as rs754171400, COSV63285253; called by mutect2, pindel, varscan2
- KLF6 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1170260252, COSV51494080, COSV99434913; called by muse, mutect2, varscan2
- KMT2B | c.5590C>T p.R1864* | Nonsense Mutation (SNP) | VAF 18/34 reads (53%) | catalogued as COSV55856587; called by muse, mutect2, varscan2
- KMT2D | c.2317del p.Q773Sfs*157 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as COSV56443963; called by mutect2, varscan2
- KRT72 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs368767777, COSV53374553; called by muse, mutect2, varscan2
- KSR1 | c.872del p.P291Hfs*36 (on ENST00000644974 / NM_001367810.1; = p.P154Hfs*36 on NM_014238.2) | Frame Shift Del (DEL) | VAF 29/60 reads (48%) | catalogued as rs750491454; called by mutect2, varscan2
- LAMA2 | c.1613A>G p.Q538R | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs1562316296, COSV101370086; ClinVar: uncertain significance; called by muse, mutect2
- LAMA4 | c.3191C>T p.T1064I (on ENST00000230538 / NM_001105206.3; = p.T1057I on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV100037645; called by muse, mutect2, varscan2
- LAMC3 | c.3452A>C p.K1151T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100735882; called by muse, mutect2, varscan2
- LARP4B | c.1295T>C p.L432S | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100295086; called by muse, mutect2, varscan2
- LFNG | c.822-1G>A p.X274_splice (on ENST00000222725 / NM_001040167.2; = p.X145_splice on NM_002304.2) | Splice Site (SNP) | VAF 25/59 reads (42%) | catalogued as COSV99761671; called by muse, mutect2, varscan2
- LGALS9 | c.231G>T p.R77S | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV100119375; called by muse, mutect2, varscan2
- LINGO2 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.094); catalogued as rs758345053, COSV100430166; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 34/74 reads (46%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMNTD1 | c.747G>A p.W249* | Nonsense Mutation (SNP) | VAF 33/84 reads (39%) | catalogued as COSV99279365; called by muse, mutect2, varscan2
- LNPK | c.104del p.N35Ifs*12 | Frame Shift Del (DEL) | VAF 31/86 reads (36%) | catalogued as rs1443101323; called by mutect2, pindel, varscan2
- LOXL3 | c.824del p.G275Afs*5 | Frame Shift Del (DEL) | VAF 26/54 reads (48%) | catalogued as rs746133895; called by mutect2, varscan2
- LRFN1 | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.84); PolyPhen benign (0.02); catalogued as COSV99952638; called by muse, mutect2, varscan2
- LRP2 | c.12326G>A p.G4109D | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.878); catalogued as COSV99786598; called by muse, mutect2, varscan2
- LRP4 | c.5504del p.G1835Afs*9 | Frame Shift Del (DEL) | VAF 30/68 reads (44%) | catalogued as rs745628337; called by mutect2, varscan2
- LRRC37A3 | c.3875T>C p.M1292T | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs139729586; called by muse, mutect2, varscan2
- LRRC37A3 | c.160C>A p.L54M | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV100140840; called by muse, mutect2, varscan2
- MAD1L1 | c.1582C>T p.R528W | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs747276194, COSV56226118; called by muse, mutect2, varscan2
- MAD1L1 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs61751745, COSV56251681, COSV99765150; called by muse, mutect2, varscan2
- MAG | c.1021del p.E341Rfs*94 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | catalogued as COSV100727606; called by mutect2, varscan2
- MAGED2 | c.1372A>G p.K458E | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV54497199, COSV54497259; called by muse, mutect2, varscan2
- MAGI2 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as COSV62651758; called by muse, mutect2, varscan2
- MAN2A1 | c.1934C>T p.A645V | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs764108733, COSV54860624; called by muse, mutect2, varscan2
- MAN2B1 | c.2090G>A p.C697Y | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99666663; called by muse, mutect2, varscan2
- MAP1S | c.2984C>T p.A995V | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs756750698, COSV60721420; called by muse, mutect2, varscan2
- MAP9 | c.1700del p.K567Rfs*13 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as rs1215313075; called by mutect2, pindel, varscan2
- MAPK11 | c.1010G>T p.W337L | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as COSV99299008; called by muse, mutect2, varscan2
- MARVELD2 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1420972013, COSV57781462; called by muse, mutect2, varscan2
- MAST3 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.441); catalogued as COSV53217858; called by muse, mutect2, varscan2
- MAVS | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100816244; called by muse, mutect2, varscan2
- MCF2 | c.311C>T p.T104I | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV100644471; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 14/23 reads (61%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MDH1B | c.1442dup p.N481Kfs*20 | Frame Shift Ins (INS) | VAF 14/34 reads (41%) | catalogued as rs1298797334; called by mutect2, varscan2
- MDM4 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as rs145156544; called by muse, mutect2, varscan2
- MECP2 | c.624G>T p.Q208H | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.647); catalogued as COSV100317841; called by muse, mutect2, varscan2
- MEDAG | c.464T>C p.V155A | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.36); PolyPhen benign (0.083); catalogued as COSV100995213; called by muse, mutect2, varscan2
- MEI1 | c.3133C>T p.L1045F | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100299608; called by muse, mutect2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | catalogued as rs745891632; called by mutect2, varscan2
- MGRN1 | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | catalogued as COSV99273787; called by muse, mutect2
- MIB2 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.079); catalogued as rs368773238, COSV61755837; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 43/63 reads (68%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MIS18BP1 | c.3007C>T p.P1003S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100172667; called by muse, mutect2, varscan2
- MKS1 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as rs369388608; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMS22L | c.458A>G p.H153R | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.086); catalogued as COSV51524793; called by muse, mutect2, varscan2
- MORC2 | c.442C>T p.P148S (on ENST00000397641 / NM_001303256.3; = p.P86S on NM_014941.3) | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99309482; called by muse, mutect2, varscan2
- MPG | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as rs112910924, COSV99549806; called by muse, mutect2, varscan2
- MPI | c.1022del p.P341Lfs*8 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as rs765310894; called by mutect2, pindel, varscan2
- MRI1 | c.988del p.H330Tfs*24 (on ENST00000040663 / NM_001031727.4; = p.H283Tfs*24 on NM_032285.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 42/104 reads (40%) | catalogued as rs751646149; called by mutect2, pindel, varscan2
- MRPL2 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs775695693, COSV99537923; called by muse, mutect2, varscan2
- MRPL40 | c.137+1G>A p.X46_splice | Splice Site (SNP) | VAF 22/60 reads (37%) | catalogued as COSV99599921; called by muse, mutect2, varscan2
- MRPS22 | c.517G>A p.V173I (on ENST00000310776 / NM_001363893.1; = p.V174I on NM_020191.4) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs867193053, COSV100168960; called by muse, mutect2, varscan2
- MRPS9 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99305872; called by muse, mutect2, varscan2
- MSL2 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV99386471; called by muse, mutect2, varscan2
- MSS51 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV100200083; called by muse, mutect2
- MTRR | c.1535G>A p.R512Q (on ENST00000264668; = p.R485Q on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs146475928; called by muse, mutect2, varscan2
- MTX2 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866538702, COSV99980787; called by muse, mutect2, varscan2
- MUC6 | c.3025A>G p.M1009V | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.159); catalogued as rs1162752436, COSV101424400; called by muse, mutect2, varscan2
- MXRA5 | c.5783G>A p.C1928Y | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99475857; called by muse, mutect2, varscan2
- MYH10 | c.3026C>T p.A1009V | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.13); catalogued as rs780518542, COSV99344112; called by muse, mutect2, varscan2
- MYH2 | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs578188627, COSV55443758; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO1E | c.1849C>T p.R617* | Nonsense Mutation (SNP) | VAF 31/66 reads (47%) | catalogued as rs1344931713, COSV55690936; called by muse, mutect2, varscan2
- MYO3A | c.4049C>T p.A1350V | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs144725179; called by muse, mutect2, varscan2
- MYO3B | c.3557C>T p.A1186V | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs940270422, COSV100509213; called by muse, mutect2, varscan2
- MYO6 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.195); catalogued as rs777201018, COSV64120550; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOM3 | c.3353A>G p.Q1118R | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV100141554; called by muse, mutect2, varscan2
- MYRF | c.789dup p.S264Qfs*74 (on ENST00000278836 / NM_001127392.3; = p.S255Qfs*74 on NM_013279.4) | Frame Shift Ins (INS) | VAF 30/73 reads (41%) | catalogued as rs769274302; called by mutect2, varscan2
- N4BP2 | c.3239A>C p.E1080A | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99788213; called by muse, mutect2, varscan2
- NAV2 | c.2237G>A p.R746Q (on ENST00000396087 / NM_001244963.2; = p.R723Q on NM_145117.5) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778831140, COSV62323310; called by muse, mutect2, varscan2
- NCALD | c.313T>C p.F105L | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99636722; called by muse, mutect2, varscan2
- NCAM1 | c.2173G>A p.V725M (on ENST00000316851 / NM_181351.5; = p.V715M on NM_000615.7) | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as rs377610168, COSV100377052; called by muse, mutect2, varscan2
- NDST1 | c.2203A>G p.T735A | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV99938635; called by muse, mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | catalogued as rs747914168; called by mutect2, varscan2
- NDUFS1 | c.1413del p.K471Nfs*6 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs1193542706, COSV99260318; called by mutect2, pindel, varscan2
- NEO1 | c.1512G>A p.M504I | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99981296; called by muse, mutect2, varscan2
- NFYA | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs776946817, COSV58198210; called by muse, mutect2, varscan2
- NIN | c.3029C>T p.T1010I | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99811701; called by muse, mutect2, varscan2
- NIPA2 | c.689G>A p.S230N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as COSV100487786; called by muse, mutect2, varscan2
- NIPAL4 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as rs374137299; called by muse, mutect2, varscan2
- NKX2-4 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100698565; called by muse, mutect2, varscan2
- NLRC3 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.185); catalogued as rs377575410; called by muse, varscan2
- NLRP10 | c.1545G>T p.Q515H | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100149478; called by muse, mutect2, varscan2
- NLRP13 | c.145del p.Q49Rfs*12 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | catalogued as rs1198298310; called by mutect2, pindel, varscan2
- NLRP2 | c.1277C>T p.T426M | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1435322954, COSV99671906; called by muse, mutect2, varscan2
- NOD1 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs772446340, COSV99767795; called by muse, varscan2
- NOP16 | c.64C>A p.L22M | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.199); catalogued as COSV99220810; called by muse, mutect2, varscan2
- NOS3 | c.1319dup p.C441Lfs*57 | Frame Shift Ins (INS) | VAF 14/30 reads (47%) | catalogued as rs749517498; called by mutect2, varscan2
- NOVA1 | c.101del p.P34Lfs*19 | Frame Shift Del (DEL) | VAF 38/91 reads (42%) | catalogued as rs765756993; called by mutect2, pindel, varscan2
- NRDC | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV100703098; called by muse, mutect2, varscan2
- NTNG1 | c.1153G>A p.V385M | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV100903408; called by muse, mutect2, varscan2
- NUMB | c.1324C>T p.R442* (on ENST00000355058; = p.R431* on NM_003744.5) | Nonsense Mutation (SNP) | VAF 25/53 reads (47%) | catalogued as COSV99389098; called by muse, mutect2, varscan2
- NUP85 | c.1184G>A p.G395D | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV99822916; called by muse, mutect2, varscan2
- OBSCN | c.14402C>T p.S4801L | Missense Mutation (SNP) | VAF 97/138 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs769020480, COSV99472973; called by muse, mutect2, varscan2
- OBSL1 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs756906456, COSV54713850; called by muse, mutect2
- OPN1SW | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV99975465; called by muse, mutect2, varscan2
- OR10C1 | c.194G>A p.R65H (on ENST00000622521; = p.R63H on NM_013941.3) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.828); catalogued as rs779708085, COSV65823122, COSV65823353; called by muse, mutect2, varscan2
- OR2A4 | c.134T>C p.L45P | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs781653671, COSV100199618; called by muse, mutect2, varscan2
- OR4A47 | c.527dup p.C177Lfs*2 | Frame Shift Ins (INS) | VAF 22/61 reads (36%) | catalogued as rs753340791; called by mutect2, pindel, varscan2
- OR4K2 | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV100064081; called by muse, mutect2, varscan2
- OR4P4 | c.268A>G p.I90V | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV58923311; called by muse, mutect2
- OR4S1 | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100180175; called by muse, mutect2, varscan2
- OR6C75 | c.599del p.L200* | Frame Shift Del (DEL) | VAF 24/48 reads (50%) | catalogued as rs746200712; called by mutect2, varscan2
- OR8D2 | c.269A>G p.N90S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100658892; called by muse, mutect2, varscan2
- OR8U1 | c.369T>A p.Y123* | Nonsense Mutation (SNP) | VAF 22/68 reads (32%) | catalogued as COSV100163773; called by muse, varscan2
- OR9K2 | c.311C>A p.P104H (on ENST00000305377; = p.P82H on NM_001005243.1) | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100543736; called by muse, mutect2, varscan2
- PACS1 | c.1617C>A p.H539Q | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.554); catalogued as COSV100269573; called by muse, mutect2, varscan2
- PAPOLA | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV53483221; called by muse, mutect2, varscan2
- PAPPA2 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 93/134 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774370341, COSV62779980; called by muse, mutect2, varscan2
- PARD3 | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 31/78 reads (40%) | catalogued as COSV60764100; called by muse, mutect2, varscan2
- PATE1 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV99986088; called by muse, mutect2
- PAX2 | c.1225G>A p.A409T (on ENST00000428433 / NM_003987.5; = p.A386T on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100694967; called by muse, mutect2, varscan2
- PCDH10 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 24/48 reads (50%) | catalogued as COSV52088148, COSV52090615; called by muse, mutect2, varscan2
- PCDH9 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as rs148716657; called by muse, mutect2, varscan2
- PCDHA11 | c.1409G>A p.G470D | Missense Mutation (SNP) | VAF 103/218 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100247699; called by muse, mutect2, varscan2
- PCDHA13 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 72/160 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.612); catalogued as rs369720251, COSV99165055; called by muse, mutect2, varscan2
- PCDHA2 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 94/205 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV65367327; called by muse, mutect2, varscan2
- PCDHA4 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.311); catalogued as rs199939862, COSV63541144; called by muse, mutect2, varscan2
- PCDHAC1 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs782119738, COSV99165056, COSV99165743; called by muse, mutect2, varscan2
- PCDHAC1 | c.677C>T p.T226I | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as COSV99165057; called by muse, mutect2, varscan2
- PCDHB12 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.107); catalogued as rs371515374, COSV53398083; called by muse, mutect2
- PCDHB15 | c.1837G>T p.G613W | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99178819; called by muse, mutect2, varscan2
- PCDHB2 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.031); catalogued as COSV50570898; called by muse, mutect2, varscan2
- PDCD10 | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as rs769106959, COSV101208503; called by muse, mutect2, varscan2
- PDE1C | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58504841; called by muse, mutect2, varscan2
- PDIA4 | c.749C>A p.S250Y | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV99618290; called by muse, varscan2
- PDIA5 | c.1157del p.P386Rfs*26 | Frame Shift Del (DEL) | VAF 30/84 reads (36%) | catalogued as rs766425459, COSV60251765; called by mutect2, pindel, varscan2
- PDLIM1 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.284); catalogued as rs768989089, COSV61473686, COSV61474241; called by muse, mutect2
- PELI2 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV50709906; called by muse, mutect2, varscan2
- PGAM1 | c.374C>A p.P125Q | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as COSV100602400; called by muse, varscan2
- PGBD2 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 9/65 reads (14%) | catalogued as rs775887214, COSV61401288; called by muse, mutect2, varscan2
- PHACTR2 | c.587dup p.N196Kfs*7 | Frame Shift Ins (INS) | VAF 16/35 reads (46%) | catalogued as rs756307843; called by mutect2, varscan2
- PHIP | c.3768_3770del p.L1257del | In Frame Del (DEL) | VAF 23/59 reads (39%) | catalogued as rs964550052; called by pindel, varscan2
- PICALM | c.1820G>A p.G607D | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.64); PolyPhen probably damaging (1); catalogued as COSV100707714; called by muse, mutect2, varscan2
- PIEZO2 | c.6851G>T p.R2284M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV99554456; called by muse, mutect2, varscan2
- PIGG | c.118C>T p.H40Y | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV99573624; called by muse, mutect2, varscan2
- PIK3C2A | c.4022G>T p.G1341V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV56402379, COSV56407470; called by muse, mutect2, varscan2
- PIK3R4 | c.2242C>T p.R748C | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs962962443, COSV100768225; called by muse, mutect2, varscan2
- PJA1 | c.104G>T p.R35M | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100824653; called by muse, mutect2, varscan2
- PKHD1 | c.3619T>C p.S1207P | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100581169; called by muse, mutect2, varscan2
- PKN1 | c.2014A>G p.S672G | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99466254; called by muse, mutect2, varscan2
- PLA2G2F | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); catalogued as rs771304346, COSV100907896; called by muse, mutect2, varscan2
- PLEC | c.13426G>T p.G4476C (on ENST00000322810 / NM_201380.4; = p.G4366C on NM_000445.5) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100510865; called by muse, mutect2
- PLEKHA1 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV64570755; called by muse, mutect2, varscan2
- PLEKHA6 | c.2537C>T p.P846L | Missense Mutation (SNP) | VAF 115/166 reads (69%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as rs200862816, COSV99691546; called by muse, mutect2, varscan2
- PNPLA7 | c.3643C>T p.R1215C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs763270925, COSV99480124; called by muse, varscan2
- PNPLA7 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs766717143, COSV99480127; called by muse, mutect2, varscan2
- POM121 | c.2939C>T p.P980L (on ENST00000434423; = p.P715L on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs145302862; called by muse, mutect2, varscan2
- PORCN | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1202991912, COSV100400297, COSV58227036; called by muse, mutect2, varscan2
- PPEF2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs768027046, COSV99714131; called by muse, mutect2, varscan2
- PPFIA3 | c.3456del p.N1153Tfs*108 | Frame Shift Del (DEL) | VAF 37/80 reads (46%) | catalogued as rs758649530; called by mutect2, pindel, varscan2
- PPP1R15A | c.751del p.R251Dfs*89 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | catalogued as COSV52338789; called by mutect2, pindel, varscan2
- PPP1R3A | c.1214C>T p.S405L | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV52895955; called by muse, mutect2, varscan2
- PRKACA | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100431762; called by muse, mutect2, varscan2
- PRMT5 | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99362765; called by muse, mutect2, varscan2
- PROC | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1343264503, CM005574, CM951015, COSV52165433; called by muse, mutect2, varscan2
- PRR19 | c.487del p.R163Gfs*4 | Frame Shift Del (DEL) | VAF 20/30 reads (67%) | catalogued as COSV100003724, COSV100003974; called by mutect2, varscan2
- PRSS22 | c.277A>G p.K93E | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.612); catalogued as COSV99361763; called by muse, mutect2, varscan2
- PRX | c.2738T>C p.I913T | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV99397471; called by muse, mutect2
- PSD | c.593del p.G198Afs*19 | Frame Shift Del (DEL) | VAF 30/61 reads (49%) | catalogued as COSV99194092; called by mutect2, pindel, varscan2
- PSME2 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1136581, COSV99395531; called by muse, mutect2, varscan2
- PTCH2 | c.3148C>T p.R1050W | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765314961, COSV100807942; called by muse, mutect2, varscan2
- PTPN23 | c.946_948del p.N316del | In Frame Del (DEL) | VAF 23/59 reads (39%) | catalogued as rs1470991120; called by mutect2, pindel, varscan2
- PTPRK | c.2744G>A p.R915Q (on ENST00000368215 / NM_001291984.2; = p.R916Q on NM_002844.4) | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs746002316, COSV63898028, COSV63904549; called by muse, mutect2, varscan2
- PTPRK | c.916A>G p.T306A | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV100949489; called by muse, mutect2, varscan2
- PTPRZ1 | c.4351T>A p.S1451T | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV101099596; called by muse, mutect2, varscan2
- PUF60 | c.273G>C p.Q91H | Missense Mutation (SNP) | VAF 64/111 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.336); catalogued as rs1268326820, COSV100512944; called by muse, mutect2, varscan2
- PWWP3B | c.1218G>A p.W406* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as COSV100530931; called by muse, mutect2, varscan2
- PXDN | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as rs749531982, COSV99412366; called by muse, mutect2, varscan2
- QRICH1 | c.1711G>T p.D571Y | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62614272; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3557C>T p.A1186V (on ENST00000330843 / NM_001002814.3; = p.A552V on NM_025151.5) | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as COSV99769701; called by muse, mutect2, varscan2
- RAP1GDS1 | c.665C>T p.T222I (on ENST00000408927 / NM_001100427.2; = p.T223I on NM_021159.5) | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV99216705; called by muse, mutect2, varscan2
- RAPGEF4 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); catalogued as COSV99909792; called by muse, mutect2, varscan2
- RAPGEF4 | c.2538del p.K846Nfs*5 | Frame Shift Del (DEL) | VAF 19/53 reads (36%) | catalogued as COSV51380239; called by mutect2, pindel, varscan2
- RASD2 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as rs1322154186, COSV53351979; called by muse, mutect2, varscan2
- RASGEF1C | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.209); catalogued as rs1386427511, COSV100745612, COSV63177061; called by muse, mutect2, varscan2
- RAVER1 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.875); catalogued as rs372689578; called by muse, mutect2, varscan2
- RBL2 | c.2304del p.Q769Rfs*5 | Frame Shift Del (DEL) | VAF 15/29 reads (52%) | catalogued as rs1340788698; called by mutect2, varscan2
- RBM10 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV100237327; called by muse, mutect2, varscan2
- RBM12 | c.2311G>T p.G771C | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV100467003; called by muse, mutect2, varscan2
- RBM26 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.534); catalogued as COSV99935825; called by muse, mutect2, varscan2
- RBM45 | c.1149dup p.A384Sfs*4 (on ENST00000616198 / NM_001365579.1; = p.A382Sfs*4 on NM_152945.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 34/64 reads (53%) | catalogued as rs749563266; called by mutect2, varscan2
- REPIN1 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 37/80 reads (46%) | catalogued as COSV68291953; called by muse, mutect2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as rs751982308; called by mutect2, varscan2
- RHOQ | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99475661; called by muse, mutect2, varscan2
- RIMS2 | c.1493C>A p.P498H (on ENST00000666250 / NM_001348490.2; = p.P306H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV99160901; called by muse, mutect2, varscan2
- RIMS2 | c.3979C>T p.R1327W | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs370268038; called by muse, mutect2, varscan2
- RMI1 | c.490G>T p.G164C | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100366052; called by muse, mutect2, varscan2
- RNF113A | c.152G>A p.C51Y | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV101006971; called by muse, mutect2, varscan2
- RNF146 | c.804_806del p.E268del (on ENST00000368314 / NM_001242850.2; = p.E267del on NM_030963.3 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 14/35 reads (40%) | catalogued as rs760706934; called by pindel, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 51/76 reads (67%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNF6 | c.1778del p.L593Yfs*2 | Frame Shift Del (DEL) | VAF 32/63 reads (51%) | catalogued as rs1199638878, COSV60419447; called by mutect2, varscan2
- ROM1 | c.134A>G p.Q45R | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99605718; called by muse, mutect2, varscan2
- ROR2 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as rs1247331053, COSV65222526; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RUSC2 | c.269A>G p.D90G | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100770598; called by muse, mutect2, varscan2
- RYR3 | c.11900C>T p.A3967V (on ENST00000389232; = p.A3968V on NM_001036.6) | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.328); catalogued as COSV101212025; called by muse, mutect2, varscan2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 28/60 reads (47%) | catalogued as rs753320334; called by mutect2, pindel, varscan2
- SASS6 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs887977995, COSV54926483; called by muse, mutect2, varscan2
- SCAF4 | c.2998T>G p.F1000V | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.968); catalogued as COSV54256745; called by muse, mutect2, varscan2
- SCFD1 | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as COSV100356064; called by muse, mutect2, varscan2
- SCLY | c.370G>A p.A124T (on ENST00000651534; = p.A116T on NM_016510.7) | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs777452792, COSV54543942; called by muse, mutect2, varscan2
- SCRIB | c.3769G>T p.A1257S | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.07); catalogued as rs200246577, COSV100252587; called by muse, mutect2, varscan2
- SCTR | c.134G>A p.C45Y | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99191507; called by muse, mutect2, varscan2
- SDK1 | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1347013293, COSV67378120; called by muse, mutect2, varscan2
- SEC16A | c.5072C>T p.T1691M | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.49); catalogued as rs372815679; called by muse, mutect2, varscan2
- SEC23IP | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776226090, COSV64832536; called by muse, mutect2, varscan2
- SEC63 | c.1586_1596delinsGAAACCTTT p.K529Rfs*4 | Frame Shift Del (DEL) | VAF 16/96 reads (17%) | catalogued as COSV64602454; called by pindel, varscan2*
- SEMA3A | c.1674A>G p.I558M | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1479200595, COSV99545354; called by muse, mutect2
- SEMA6D | c.2429del p.P810Rfs*10 (on ENST00000316364 / NM_153618.2; = p.P748Rfs*10 on NM_020858.2) | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | catalogued as COSV60382948; called by mutect2, pindel
- SERINC2 | c.433G>A p.V145M (on ENST00000373709 / NM_178865.5; = p.V149M on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs140666908; called by muse, mutect2, varscan2
- SFMBT2 | c.2194G>A p.A732T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.023); catalogued as rs780341005, COSV100738422; called by muse, varscan2
- SH2D3A | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as rs771362495, COSV99837808; called by muse, varscan2
- SH3TC1 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.138); catalogued as rs766520849, COSV99794428; called by muse, mutect2, varscan2
- SHANK3 | c.1760C>A p.P587H | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99436239; called by muse, varscan2
- SHMT1 | c.1381G>A p.V461M | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as rs769762115, COSV100363461; called by muse, mutect2, varscan2
- SI | c.887del p.L296* | Frame Shift Del (DEL) | VAF 26/77 reads (34%) | catalogued as rs769103567, COSV52291108; called by mutect2, pindel, varscan2
- SIRT7 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs560137203, COSV100155411, COSV100155607; called by muse, mutect2, varscan2
- SLC12A7 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV53758772; called by muse, mutect2, varscan2
- SLC14A1 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs750695032, COSV58931993; called by muse, mutect2, varscan2
- SLC17A4 | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 65/121 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs369079605; called by muse, mutect2, varscan2
- SLC17A9 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0.019); catalogued as rs752324785, COSV100947705; called by muse, mutect2, varscan2
- SLC22A1 | c.789G>A p.W263* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as rs1204306128, COSV100266415; called by muse, mutect2, varscan2
- SLC22A4 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 82/151 reads (54%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.49); catalogued as rs767093107, COSV99569171; called by muse, mutect2, varscan2
- SLC25A4 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99861165; called by muse, mutect2, varscan2
- SLC2A11 | c.770G>A p.R257H (on ENST00000345044 / NM_001024938.4; = p.R264H on NM_030807.5) | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as rs755792944, COSV99741150; called by muse, mutect2, varscan2
- SLC2A6 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1160012528, COSV99390091; called by muse, mutect2, varscan2
- SLC2A7 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.966); catalogued as rs543583633, COSV101280749; called by muse, mutect2, varscan2
- SLC35F5 | c.742del p.C248Afs*22 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | catalogued as rs577214214; called by mutect2, varscan2
- SLC5A11 | c.1655G>A p.S552N | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.157); catalogued as COSV100762676; called by muse, mutect2, varscan2
- SLC8A2 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs781697270, COSV52640297, COSV99369666; called by muse, mutect2, varscan2
- SLMAP | c.1519C>T p.L507F (on ENST00000428312 / NM_001377924.1; = p.L569F on NM_007159.5) | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.776); catalogued as COSV99908063; called by muse, mutect2, varscan2
- SMARCA4 | c.4363C>T p.P1455S | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as COSV60790904; called by muse, mutect2, varscan2
- SMC1A | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781817340, COSV59128385; called by muse, mutect2, varscan2
- SMC5 | c.2780G>T p.R927M | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100746964; called by muse, mutect2, varscan2
- SMPDL3B | c.1289A>T p.Y430F | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100874554; called by muse, mutect2, varscan2
- SNX32 | c.477_478del p.L161Gfs*30 | Frame Shift Del (DEL) | VAF 36/102 reads (35%) | catalogued as rs773735747; called by pindel, varscan2
- SP7 | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs757811295, COSV100381920; called by muse, mutect2, varscan2
- SPAG17 | c.3833C>T p.P1278L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV100307981; called by muse, mutect2, varscan2
- SPEG | c.4081A>G p.S1361G | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV100403306; called by muse, mutect2, varscan2
- SPEG | c.8609G>A p.S2870N | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100403308; called by muse, mutect2
- SPEM1 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs765266826, COSV100080812; called by muse, mutect2, varscan2
- SPIRE2 | c.1575+6_1575+9del p.X525_splice | Splice Site (DEL) | VAF 39/95 reads (41%) | catalogued as rs749846493; called by pindel, varscan2
- SPIRE2 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100988732, COSV100988957; called by muse, mutect2, varscan2
- SPOUT1 | c.102del p.K34Nfs*7 | Frame Shift Del (DEL) | VAF 14/23 reads (61%) | catalogued as rs749421754; ClinVar: uncertain significance; called by mutect2, varscan2
- SPP2 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs149868175; called by muse, mutect2, varscan2
- SPPL2C | c.1588G>A p.G530S | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.103); catalogued as COSV100233934; called by muse, mutect2, varscan2
- SPTBN5 | c.1756G>A p.G586R | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as rs769365811, COSV100310688; called by muse, mutect2, varscan2
- SRCAP | c.5633dup p.P1879Tfs*21 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | catalogued as rs748467821; called by mutect2, varscan2
- SREK1IP1 | c.271del p.R91Gfs*67 | Frame Shift Del (DEL) | VAF 46/58 reads (79%) | catalogued as rs750306056; called by mutect2, varscan2
- SRPX | c.523G>C p.V175L | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.815); catalogued as COSV100655894; called by muse, mutect2, varscan2
- SSRP1 | c.929T>G p.L310R | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV53481038, COSV99554740; called by muse, mutect2, varscan2
- ST8SIA5 | c.533G>A p.C178Y | Missense Mutation (SNP) | VAF 42/89 reads (47%) | PolyPhen probably damaging (0.962); catalogued as COSV100164510; called by muse, mutect2, varscan2
- STK25 | c.261+2T>C p.X87_splice | Splice Site (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100346046; called by muse, mutect2
- STX10 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs1280950416, COSV52834490; called by muse, varscan2
- SUN1 | c.1622C>T p.A541V (on ENST00000405266 / NM_001367651.1; = p.A421V on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.057); catalogued as COSV67452215; called by muse, mutect2, varscan2
- SUPT20HL2 | c.1196C>T p.T399I | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.2); catalogued as rs1569196527; called by muse, mutect2, varscan2
- SVEP1 | c.6263C>T p.S2088L | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.137); catalogued as rs1476319933, COSV99928319; called by muse, mutect2, varscan2
- SYN2 | c.978C>T p.Y326= | Splice Region (SNP) | VAF 23/52 reads (44%) | catalogued as COSV99825930; called by muse, mutect2, varscan2
- SYNE2 | c.14203G>A p.V4735I | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs538224852, COSV100646723; ClinVar: benign; called by muse, varscan2
- SZT2 | c.8017G>C p.A2673P (on ENST00000634258 / NM_001365999.1; = p.A2616P on NM_015284.4) | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.898); catalogued as COSV100986887, COSV65176138; called by muse, mutect2, varscan2
- TAF1 | c.3800C>T p.A1267V (on ENST00000373790 / NM_138923.4; = p.A1288V on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1475300074, COSV52115620, COSV52119736; called by muse, mutect2, varscan2
- TAS1R3 | c.1812del p.L606Wfs*43 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs777573279, COSV100229689; called by mutect2, pindel, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 14/29 reads (48%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBC1D25 | c.1891G>A p.D631N | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.894); catalogued as rs781884817, COSV100952106; called by muse, mutect2, varscan2
- TBC1D2B | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100316836; called by muse, mutect2, varscan2
- TBP | c.382A>G p.T128A | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.952); catalogued as COSV100027172; called by muse, mutect2, varscan2
- TCF19 | c.72del p.A25Pfs*72 | Frame Shift Del (DEL) | VAF 41/90 reads (46%) | catalogued as rs751224053; called by mutect2, pindel, varscan2
- TCF7L2 | c.1457G>A p.C486Y (on ENST00000355995 / NM_001367943.1; = p.C463Y on NM_030756.5) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53340274; called by muse, mutect2, varscan2
- TCTN3 | c.1573C>T p.Q525* | Nonsense Mutation (SNP) | VAF 37/87 reads (43%) | catalogued as COSV99796552; called by muse, mutect2, varscan2
- TEAD2 | c.883dup p.H295Pfs*19 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | catalogued as rs763321097; called by mutect2, varscan2
- TEX15 | c.7282C>T p.Q2428* (on ENST00000256246; = p.Q2811* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 44/87 reads (51%) | catalogued as COSV99820727; called by muse, mutect2, varscan2
- THBS3 | c.914del p.P305Lfs*181 | Frame Shift Del (DEL) | VAF 21/122 reads (17%) | catalogued as rs757853564; called by mutect2, pindel, varscan2
- THEM5 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 105/146 reads (72%) | SIFT tolerated (0.08); PolyPhen benign (0.095); catalogued as rs759063830, COSV64312680; called by muse, mutect2, varscan2
- THUMPD3 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs577863688, COSV61506982; called by muse, varscan2
- TKT | c.1781G>T p.R594I | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as COSV99964859; called by muse, mutect2, varscan2
- TLR9 | c.1399A>G p.R467G | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100645555; called by muse, mutect2, varscan2
- TMC3 | c.3211C>T p.P1071S | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as rs1407022287, COSV63923290; called by muse, mutect2, varscan2
- TMEM132B | c.1222G>A p.V408I | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as rs554504714, COSV54760030; called by muse, mutect2, varscan2
- TMEM242 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.765); catalogued as COSV100900859; called by muse, mutect2, varscan2
- TMEM245 | c.1806G>A p.W602* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as COSV101002201; called by muse, mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 24/47 reads (51%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TNPO1 | c.2530del p.C844Vfs*45 | Frame Shift Del (DEL) | VAF 18/39 reads (46%) | catalogued as rs757314136; called by mutect2, varscan2
- TNS3 | c.1298G>A p.G433D | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100234774; called by muse, mutect2, varscan2
- TNXB | c.4705G>A p.D1569N (on ENST00000647633; = p.D1322N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs1280340355, COSV100925874; called by muse, mutect2, varscan2
- TOGARAM1 | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as COSV63892342; called by muse, mutect2, varscan2
- TOR1AIP2 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 78/109 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as rs772856426, COSV100857265, COSV100857437; called by muse, mutect2, varscan2
- TRAM1L1 | c.664_666del p.L223del | In Frame Del (DEL) | VAF 14/24 reads (58%) | catalogued as rs763927939; called by pindel, varscan2
- TRIM17 | c.821dup p.T275Nfs*14 | Frame Shift Ins (INS) | VAF 30/184 reads (16%) | catalogued as rs758372115; called by mutect2, varscan2
- TRIM22 | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV101181202; called by muse, mutect2, varscan2
- TRIM26 | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs754923872, COSV68963228; called by muse, mutect2, varscan2
- TRIM33 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.964); catalogued as rs527615130, COSV100635048; called by muse, mutect2, varscan2
- TRIM51 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 99/252 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753748857, COSV55265374; called by muse, mutect2, varscan2
- TRIO | c.4045G>A p.E1349K | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.53); catalogued as COSV100709895; called by muse, mutect2, varscan2
- TRIOBP | c.5554C>T p.R1852C (on ENST00000644935 / NM_001039141.3; = p.R139C on NM_007032.5) | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368185393; called by muse, mutect2, varscan2
- TRMT13 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99790600; called by muse, varscan2
- TRMT2A | c.663_665del p.N221del | In Frame Del (DEL) | VAF 20/40 reads (50%) | catalogued as rs879377585; called by pindel, varscan2
- TSC2 | c.4022G>A p.S1341N | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as rs1451479803, COSV99237177; called by muse, mutect2, varscan2
- TSKS | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs530946536, COSV55872835; called by muse, mutect2, varscan2
- TSSK1B | c.1075del p.Q359Nfs*43 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | catalogued as rs747842861, COSV101181233; called by mutect2, pindel, varscan2
- TTC23 | c.1062G>T p.E354D | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV100018392; called by muse, mutect2, varscan2
- TTC9C | c.260C>A p.P87H | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV99584539; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | catalogued as rs763254614; called by mutect2, varscan2
- TTLL13P | c.763T>C p.C255R | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100296410; called by muse, mutect2, varscan2
- TTN | c.30206A>G p.E10069G (on ENST00000591111; = p.E9142G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/82 reads (45%) | PolyPhen benign (0.055); catalogued as rs1374067450, COSV100594947; called by muse, mutect2, varscan2
- UBOX5 | c.1589C>T p.P530L | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs201389796, COSV53907399; called by muse, mutect2, varscan2
- UNC5B | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.461); catalogued as rs763976725, COSV100100229, COSV58982240; called by muse, mutect2, varscan2
- UNC79 | c.1574G>A p.R525Q (on ENST00000393151 / NM_001346218.2; = p.R348Q on NM_020818.5) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs200477456, COSV99825931; called by muse, mutect2, varscan2
- UQCR11 | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101650767; called by muse, mutect2, varscan2
- UROC1 | c.920del p.K307Rfs*77 | Frame Shift Del (DEL) | VAF 17/43 reads (40%) | catalogued as rs754361807; called by mutect2, varscan2
- UROC1 | c.23G>A p.C8Y | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.825); catalogued as COSV99330872; called by muse, mutect2, varscan2
- USP26 | c.1044del p.F348Lfs*7 | Frame Shift Del (DEL) | VAF 32/77 reads (42%) | catalogued as CM077651, COSV63708747; called by mutect2, varscan2
- USP6 | c.2293G>A p.A765T | Missense Mutation (SNP) | VAF 65/126 reads (52%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.289); catalogued as rs748575730, COSV100003040; called by muse, mutect2, varscan2
- USP6 | c.3752dup p.S1252Qfs*12 | Frame Shift Ins (INS) | VAF 42/132 reads (32%) | catalogued as rs754083634; called by mutect2, varscan2
- USP9X | c.1287G>T p.Q429H | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs775088649, COSV100198509; called by muse, mutect2, varscan2
- VEGFA | c.464G>A p.R155H (on ENST00000523873 / NM_001171623.1; = p.R335H on NM_003376.6) | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs774265827, COSV57879039; called by muse, mutect2, varscan2
- VPS4A | c.700G>T p.G234W | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776308848, COSV99651834; called by muse, mutect2, varscan2
- VTN | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99411997; called by muse, mutect2, varscan2
- VWA3B | c.2731del p.Q911Kfs*23 | Frame Shift Del (DEL) | VAF 25/61 reads (41%) | catalogued as rs1558726408; called by mutect2, pindel, varscan2
- WAPL | c.2485A>G p.K829E | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.514); catalogued as COSV99556277; called by muse, mutect2, varscan2
- WASHC2A | c.3320C>T p.P1107L | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs1162979607; called by muse, mutect2, varscan2
- WBP1 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.998); catalogued as rs566740889, COSV99270306; called by muse, mutect2, varscan2
- WBP1 | c.552del p.H185Ifs*10 | Frame Shift Del (DEL) | VAF 36/129 reads (28%) | catalogued as rs773064295, COSV51967888; called by mutect2, pindel, varscan2
- WDFY2 | c.287T>C p.I96T | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99986837; called by muse, mutect2, varscan2
- WDR33 | c.3784C>T p.R1262* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100205236; called by muse, mutect2, varscan2
- WDR45 | c.500G>T p.G167V (on ENST00000376372 / NM_001029896.2; = p.G168V on NM_007075.3) | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100540099; called by muse, mutect2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 38/44 reads (86%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WRAP53 | c.1565del p.A522Gfs*26 | Frame Shift Del (DEL) | VAF 34/74 reads (46%) | catalogued as rs373064567, COSV56832921, COSV56833408; called by mutect2, pindel, varscan2
- WSCD1 | c.907del p.R303Gfs*125 | Frame Shift Del (DEL) | VAF 48/139 reads (35%) | catalogued as rs1237564131; called by mutect2, pindel, varscan2
- XAGE3 | c.162_164del p.E54del | In Frame Del (DEL) | VAF 64/206 reads (31%) | catalogued as rs781916947; called by pindel, varscan2
- XIRP2 | c.2359G>A p.A787T (on ENST00000628543; = p.A962T on NM_152381.6) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV99738691; called by muse, mutect2, varscan2
- XRCC1 | c.1568C>T p.T523M | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs765053443, COSV99486247; called by muse, mutect2, varscan2
- XYLT1 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.166); catalogued as rs1567345180, COSV99760382; called by muse, mutect2, varscan2
- YIPF5 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as COSV99187910; called by muse, mutect2, varscan2
- YTHDC2 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99362904; called by muse, mutect2, varscan2
- ZBED4 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as rs150734381; called by muse, mutect2, varscan2
- ZBTB1 | c.1147del p.S383Vfs*6 | Frame Shift Del (DEL) | VAF 22/44 reads (50%) | catalogued as rs747075448, COSV62437585; called by mutect2, varscan2
- ZC3H11A | c.1452G>T p.R484S | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100142156; called by muse, mutect2, varscan2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as rs745875253; called by mutect2, varscan2
- ZDBF2 | c.5624del p.K1875Rfs*39 | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | catalogued as rs770232797, COSV65623567; called by mutect2, varscan2
- ZDHHC9 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV64096484; called by muse, mutect2, varscan2
- ZFR2 | c.563del p.P188Rfs*239 | Frame Shift Del (DEL) | VAF 37/90 reads (41%) | catalogued as rs764459144; called by mutect2, pindel, varscan2
- ZFX | c.1507T>G p.L503V | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100457310; called by muse, mutect2, varscan2
- ZGPAT | c.748T>C p.F250L | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100203083; called by muse, mutect2, varscan2
- ZMIZ2 | c.2144G>A p.S715N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs758583516, COSV99536583; called by muse, mutect2, varscan2
- ZMYM3 | c.2791G>A p.D931N | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs766683638, COSV58739848; called by muse, mutect2
- ZMYND8 | c.3512C>A p.T1171K (on ENST00000311275 / NM_001363741.2; = p.T1145K on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as COSV53698417, COSV99519573; called by muse, mutect2, varscan2
- ZNF22 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs1311422923, COSV53584526; called by muse, mutect2, varscan2
- ZNF251 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.037); catalogued as rs777430092, COSV99478150; called by muse, mutect2, varscan2
- ZNF347 | c.246G>A p.W82* | Nonsense Mutation (SNP) | VAF 43/88 reads (49%) | catalogued as COSV100498130; called by muse, mutect2, varscan2
- ZNF486 | c.607del p.I203Lfs*28 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | catalogued as rs1555718177; called by mutect2, pindel, varscan2
- ZNF496 | c.1321G>A p.G441R | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs145725779; called by muse, mutect2, varscan2
- ZNF644 | c.871del p.R291Efs*7 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | catalogued as rs749473342; called by mutect2, varscan2
- ZNF697 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV70284001; called by muse, mutect2, varscan2
- ZNF700 | c.377G>A p.C126Y | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.998); catalogued as rs780159016, COSV99583269; called by muse, mutect2, varscan2
- ZNF778 | c.1810C>A p.L604I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV60602862; called by muse, mutect2, varscan2
- ZNF780B | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs866042253, COSV99665267; called by muse, mutect2, varscan2
- ZNF785 | c.850T>C p.Y284H | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.95); catalogued as COSV101235632; called by muse, mutect2, varscan2
- ZNF878 | c.507del p.K169Nfs*44 | Frame Shift Del (DEL) | VAF 30/82 reads (37%) | catalogued as rs773648883, COSV72155908; called by mutect2, pindel, varscan2
- ZZEF1 | c.6655C>T p.R2219C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs752808355, COSV101067478; called by muse, varscan2
- ABCA10 | c.4585del p.I1529Lfs*56 | Frame Shift Del (DEL) | VAF 29/75 reads (39%) | called by mutect2, pindel, varscan2
- ACACA | c.6527G>A p.R2176Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AGXT2 | c.1217del p.N406Tfs*11 | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | called by mutect2, pindel, varscan2
- AL645922.1 | c.1375_1376del p.S459Cfs*16 | Frame Shift Del (DEL) | VAF 31/86 reads (36%) | called by pindel, varscan2
- AP1M1 | c.370del p.Q124Rfs*113 | Frame Shift Del (DEL) | VAF 32/86 reads (37%) | called by mutect2, pindel, varscan2
- ARID1B | c.1938del p.G647Efs*8 | Frame Shift Del (DEL) | VAF 41/87 reads (47%) | called by mutect2, pindel, varscan2
- ASH1L | c.6013_6014del p.K2005Efs*19 | Frame Shift Del (DEL) | VAF 15/69 reads (22%) | called by mutect2, pindel, varscan2
- ATF7IP | c.959dup p.N320Kfs*4 | Frame Shift Ins (INS) | VAF 16/34 reads (47%) | called by mutect2, varscan2
- BTBD2 | c.1090del p.R364Afs*57 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | called by mutect2, varscan2
- C1QL3 | c.581dup p.N194Kfs*7 | Frame Shift Ins (INS) | VAF 14/32 reads (44%) | called by mutect2, varscan2
- CACNA1D | c.1993del p.S665Pfs*38 (on ENST00000350061 / NM_001128840.3; = p.S685Pfs*38 on NM_000720.4) | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel, varscan2
- CACNA1I | c.5837del p.P1946Qfs*91 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | called by mutect2, pindel, varscan2
- CCNB3 | c.804del p.F268Lfs*19 | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | called by mutect2, pindel, varscan2
- CHD1 | c.634_637del p.Q212Lfs*36 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 23/59 reads (39%) | called by mutect2, pindel, varscan2
- CLMN | c.2594del p.K865Rfs*10 | Frame Shift Del (DEL) | VAF 26/68 reads (38%) | called by mutect2, varscan2
- COL4A2 | c.450del p.G151Afs*95 | Frame Shift Del (DEL) | VAF 31/78 reads (40%) | called by mutect2, pindel, varscan2
- CPVL | c.1251del p.V418Ffs*24 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | called by mutect2, varscan2
- CREB3L1 | c.627del p.S210Afs*53 | Frame Shift Del (DEL) | VAF 17/50 reads (34%) | called by mutect2, pindel, varscan2
- CTNNAL1 | c.1102-3dup | Splice Region (INS) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- CTSH | c.875del p.N292Mfs*8 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | called by mutect2, pindel, varscan2
- CUL4B | c.923del p.L308Cfs*30 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- DNAH7 | c.8616dup p.L2873Tfs*5 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | called by mutect2, pindel, varscan2
- DOCK3 | c.3386del p.N1129Mfs*11 | Frame Shift Del (DEL) | VAF 24/63 reads (38%) | called by mutect2, pindel, varscan2
- DVL2 | c.170del p.F57Sfs*11 | Frame Shift Del (DEL) | VAF 39/95 reads (41%) | called by mutect2, pindel, varscan2
- EFHC2 | c.1414_1415dup p.N473Gfs*11 | Frame Shift Ins (INS) | VAF 21/59 reads (36%) | called by mutect2, pindel, varscan2
- EIF4A1 | c.1169_1171del p.F390del | In Frame Del (DEL) | VAF 31/84 reads (37%) | called by mutect2, pindel, varscan2
- ELAPOR1 | c.1018_1019dup p.A341Rfs*29 | Frame Shift Ins (INS) | VAF 38/88 reads (43%) | called by mutect2, varscan2
- ENTPD8 | c.592_594del p.E198del | In Frame Del (DEL) | VAF 26/63 reads (41%) | called by pindel, varscan2
- EPB41L4A | c.885dup p.R296* | Frame Shift Ins (INS) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- ERMARD | c.918del p.F306Lfs*12 | Frame Shift Del (DEL) | VAF 56/131 reads (43%) | called by mutect2, pindel, varscan2
- FANK1 | c.805del p.A269Pfs*3 | Frame Shift Del (DEL) | VAF 20/61 reads (33%) | called by mutect2, pindel, varscan2
- FBN1 | c.905del p.G302Vfs*28 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | called by mutect2, pindel, varscan2
- FBXW10 | c.2361del p.K787Nfs*31 | Frame Shift Del (DEL) | VAF 31/166 reads (19%) | called by mutect2, pindel, varscan2
- FGFR1OP2 | c.369_371del p.I123del | In Frame Del (DEL) | VAF 10/31 reads (32%) | called by pindel, varscan2
- GBP6 | c.1035dup p.T346Hfs*15 | Frame Shift Ins (INS) | VAF 32/76 reads (42%) | called by mutect2, pindel, varscan2
- GDF2 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GFPT1 | c.446_447del p.T149Rfs*8 | Frame Shift Del (DEL) | VAF 24/86 reads (28%) | called by pindel, varscan2
- GLIS2 | c.86del p.G29Vfs*33 | Frame Shift Del (DEL) | VAF 26/74 reads (35%) | called by mutect2, pindel, varscan2
- GPM6B | c.375_377del p.T126del | In Frame Del (DEL) | VAF 22/58 reads (38%) | called by pindel, varscan2
- HCFC1 | c.2274del p.S759Vfs*28 | Frame Shift Del (DEL) | VAF 44/116 reads (38%) | called by mutect2, pindel, varscan2
- HCFC2 | c.353del p.P118Lfs*43 | Frame Shift Del (DEL) | VAF 45/132 reads (34%) | called by pindel, varscan2
- HCRTR2 | c.81del p.L29* | Frame Shift Del (DEL) | VAF 40/95 reads (42%) | called by mutect2, pindel, varscan2
- IFIT1B | c.687T>A p.D229E | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- IGHG3 | c.12G>T p.K4N | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); called by muse, mutect2
- IGSF9B | c.1260del p.Y421Ifs*37 | Frame Shift Del (DEL) | VAF 25/64 reads (39%) | called by mutect2, pindel, varscan2
- KIF1C | c.2742del p.S915Rfs*173 | Frame Shift Del (DEL) | VAF 25/57 reads (44%) | called by mutect2, pindel, varscan2
- KMT2B | c.7151_7152del p.H2384Lfs*4 | Frame Shift Del (DEL) | VAF 43/100 reads (43%) | called by mutect2, pindel, varscan2
- KNL1 | c.5516dup p.N1839Kfs*8 (on ENST00000346991 / NM_170589.5; = p.N1813Kfs*8 on NM_144508.5) | Frame Shift Ins (INS) | VAF 24/82 reads (29%) | called by mutect2, pindel, varscan2
- KRTAP10-9 | c.531del p.C178Afs*203 | Frame Shift Del (DEL) | VAF 80/192 reads (42%) | called by mutect2, pindel, varscan2
- LAMA3 | c.9360dup p.T3121Hfs*43 (on ENST00000313654 / NM_198129.4; = p.T1512Hfs*43 on NM_000227.6) | Frame Shift Ins (INS) | VAF 18/77 reads (23%) | called by mutect2, pindel, varscan2
- LAMP1 | c.456del p.K152Nfs*12 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | called by mutect2, pindel, varscan2
- LENG9 | c.875del p.P292Lfs*14 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | called by mutect2, pindel, varscan2
- LIG1 | c.703del p.R235Gfs*9 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | called by mutect2, varscan2
- LTBP4 | c.3134del p.G1045Afs*48 (on ENST00000308370 / NM_001042544.1; = p.G1008Afs*48 on NM_003573.2) | Frame Shift Del (DEL) | VAF 39/93 reads (42%) | called by mutect2, pindel, varscan2
- MCM4 | c.1885del p.T629Qfs*18 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- MCPH1 | c.1402del p.T468Pfs*32 | Frame Shift Del (DEL) | VAF 9/18 reads (50%) | called by mutect2, pindel, varscan2
- MED1 | c.117dup p.V40Cfs*40 | Frame Shift Ins (INS) | VAF 28/66 reads (42%) | called by mutect2, pindel, varscan2
- MGAM | c.3629del p.G1210Efs*23 | Frame Shift Del (DEL) | VAF 52/127 reads (41%) | called by mutect2, pindel, varscan2
- MOV10L1 | c.1226del p.G409Efs*29 | Frame Shift Del (DEL) | VAF 42/105 reads (40%) | called by mutect2, pindel, varscan2
- MPRIP | c.1090del p.L364Cfs*19 | Frame Shift Del (DEL) | VAF 42/130 reads (32%) | called by pindel, varscan2
- NCKAP5 | c.4659del p.E1554Rfs*45 | Frame Shift Del (DEL) | VAF 23/51 reads (45%) | called by mutect2, pindel, varscan2
- NCR2 | c.588_589del p.F197Lfs*69 | Frame Shift Del (DEL) | VAF 42/128 reads (33%) | called by pindel, varscan2
- NDUFS2 | c.621_624del p.E208Rfs*54 | Frame Shift Del (DEL) | VAF 17/91 reads (19%) | called by mutect2, pindel, varscan2
- NFASC | c.494del p.P165Rfs*12 (on ENST00000339876 / NM_001378329.1; = p.P159Rfs*12 on NM_015090.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 31/127 reads (24%) | called by mutect2, pindel, varscan2
- OGA | c.1809del p.I604Lfs*17 | Frame Shift Del (DEL) | VAF 16/35 reads (46%) | called by mutect2, pindel, varscan2
- P3H3 | c.833del p.G278Afs*42 | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | called by mutect2, pindel, varscan2
- PADI1 | c.1518_1521del p.E507Rfs*12 | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | called by pindel, varscan2
- PDE7A | c.1179dup p.Y394Ifs*14 (on ENST00000401827 / NM_001242318.3; = p.Y368Ifs*14 on NM_002603.4) | Frame Shift Ins (INS) | VAF 22/58 reads (38%) | called by mutect2, varscan2
- PDZD4 | c.302del p.P101Qfs*44 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | called by mutect2, varscan2
- PNISR | c.311del p.P104Lfs*58 | Frame Shift Del (DEL) | VAF 34/98 reads (35%) | called by mutect2, pindel, varscan2
- PRR11 | c.724_725del p.S242Ffs*3 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by pindel, varscan2
- PTGER2 | c.849dup p.A284Cfs*5 | Frame Shift Ins (INS) | VAF 27/90 reads (30%) | called by mutect2, pindel, varscan2
- PTPN23 | c.4536del p.L1513Wfs*71 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | called by mutect2, pindel, varscan2
- PTPRC | c.2415dup p.A806Sfs*21 | Frame Shift Ins (INS) | VAF 37/70 reads (53%) | called by mutect2, pindel, varscan2
- PUM2 | c.1520_1522del p.P507del | In Frame Del (DEL) | VAF 28/66 reads (42%) | called by pindel, varscan2
- RBM39 | c.1226-3del | Splice Region (DEL) | VAF 15/32 reads (47%) | called by mutect2, pindel, varscan2
- RNF115 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | called by mutect2, varscan2
- RP1 | c.4941del p.P1648Lfs*62 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- RTF1 | c.2115del p.K705Nfs*32 | Frame Shift Del (DEL) | VAF 15/36 reads (42%) | called by mutect2, pindel, varscan2
- RXFP2 | c.2036del p.F679Sfs*8 | Frame Shift Del (DEL) | VAF 30/59 reads (51%) | called by mutect2, pindel, varscan2
- SGK1 | c.60del p.F20Lfs*24 | Frame Shift Del (DEL) | VAF 23/56 reads (41%) | called by mutect2, pindel, varscan2
- SLAIN1 | c.930dup p.G311Rfs*4 (on ENST00000466548; = p.G48Rfs*4 on NM_144595.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 18/44 reads (41%) | called by mutect2, varscan2
- SLC9A1 | c.780del p.F260Lfs*37 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, varscan2
- SLCO1B1 | c.626del p.L209* | Frame Shift Del (DEL) | VAF 29/78 reads (37%) | called by mutect2, pindel, varscan2
- SLITRK1 | c.445del p.A149Pfs*5 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
- SPEN | c.2549dup p.P851Afs*5 | Frame Shift Ins (INS) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- SPESP1 | c.688dup p.I230Nfs*5 | Frame Shift Ins (INS) | VAF 7/19 reads (37%) | called by mutect2, varscan2
- SPOPL | c.130del p.C44Vfs*9 | Frame Shift Del (DEL) | VAF 19/40 reads (48%) | called by mutect2, pindel, varscan2
- STK17A | c.210del p.X70_splice | Splice Site (DEL) | VAF 18/50 reads (36%) | called by mutect2, pindel, varscan2
- STRADA | c.1133_1136del p.F378Sfs*40 (on ENST00000336174 / NM_001363786.1; = p.F341Sfs*40 on NM_001003786.3) | Frame Shift Del (DEL) | VAF 20/44 reads (45%) | called by pindel, varscan2
- TDRD5 | c.1907del p.L636Cfs*16 | Frame Shift Del (DEL) | VAF 24/153 reads (16%) | called by mutect2, pindel, varscan2
- TFCP2L1 | c.1279dup p.Q427Pfs*29 | Frame Shift Ins (INS) | VAF 29/77 reads (38%) | called by mutect2, pindel, varscan2
- TRPM1 | c.2277del p.T760Pfs*110 | Frame Shift Del (DEL) | VAF 24/56 reads (43%) | called by mutect2, varscan2
- TSPYL2 | c.1094del p.F365Sfs*32 | Frame Shift Del (DEL) | VAF 35/84 reads (42%) | called by mutect2, pindel, varscan2
- UBE3A | c.320_322del p.S107del | In Frame Del (DEL) | VAF 31/66 reads (47%) | called by mutect2, pindel, varscan2
- UNC5C | c.1471del p.Q491Kfs*15 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | called by mutect2, pindel, varscan2
- USP9X | c.82del p.L28Sfs*51 | Frame Shift Del (DEL) | VAF 31/96 reads (32%) | called by mutect2, pindel, varscan2
- VPS52 | c.1503del p.L502Wfs*63 | Frame Shift Del (DEL) | VAF 21/76 reads (28%) | called by mutect2, pindel, varscan2
- WDR5 | c.648del p.V217Cfs*4 | Frame Shift Del (DEL) | VAF 48/114 reads (42%) | called by mutect2, varscan2
- ZHX2 | c.451_452del p.V151Lfs*23 | Frame Shift Del (DEL) | VAF 18/43 reads (42%) | called by pindel, varscan2
- ZNF438 | c.1198del p.R400Gfs*16 | Frame Shift Del (DEL) | VAF 49/124 reads (40%) | called by mutect2, pindel, varscan2
- ZNF592 | c.2963G>A p.C988Y | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABO | c.849C>T p.C283= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as COSV101505930; called by muse, mutect2, varscan2
- AC242842.3 | c.1149G>A p.Q383= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs1263461411; called by muse, mutect2, varscan2
- ADAMTS13 | c.3594G>A p.E1198= | Silent (SNP) | VAF 52/100 reads (52%) | catalogued as rs1465710121, COSV99390089; called by muse, mutect2, varscan2
- ADAMTS19 | c.2799C>T p.C933= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs754348548, COSV50735590; called by muse, mutect2, varscan2
- ADNP2 | c.1761G>A p.S587= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs150632789; called by muse, mutect2, varscan2
- ADRB2 | c.222A>G p.S74= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs748205706, COSV100019093; called by muse, mutect2, varscan2
- AKR1E2 | c.102C>T p.F34= | Silent (SNP) | VAF 64/128 reads (50%) | catalogued as rs867771855, COSV53630792; called by muse, mutect2
- ALMS1 | c.11368C>T p.L3790= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV100041186; called by muse, mutect2, varscan2
- ALOXE3 | c.1233C>T p.C411= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as rs1367643591, COSV100559612; called by muse, mutect2, varscan2
- AMOT | c.2482C>T p.L828= (on ENST00000371959 / NM_001113490.1; = p.L419= on NM_133265.3) | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV100494741; called by muse, mutect2, varscan2
- ANKMY1 | c.1827C>T p.T609= | Silent (SNP) | VAF 39/82 reads (48%) | catalogued as rs201754245, COSV99801842; called by muse, mutect2, varscan2
- AP1B1 | c.2730G>A p.A910= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as rs373101993; called by muse, mutect2, varscan2
- ARAP1 | c.1371C>T p.Y457= (on ENST00000393609 / NM_001040118.2; = p.Y212= on NM_015242.4) | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as rs765497754, COSV61995429; called by muse, mutect2, varscan2
- ARHGAP22 | c.1098C>T p.C366= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as rs1483189813, COSV99984498; called by muse, mutect2, varscan2
- ARHGAP36 | c.1584A>G p.P528= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV99357271; called by muse, mutect2, varscan2
- ARHGEF10 | c.3837C>T p.S1279= (on ENST00000398564; = p.S1254= on NM_014629.4) | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs764863519, COSV100033547; called by muse, mutect2, varscan2
- ARVCF | c.495G>A p.R165= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99598944; called by muse, mutect2, varscan2
- ASCC3 | c.4023G>A p.T1341= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs140450400; called by muse, mutect2, varscan2
198 further variants in this file (0 protein-altering or splice-affecting, 183 silent, 15 other) are not listed here.
